Somatic mutation profile of tumor specimen TARGET-20-PANLIZ-09A (aliquot TARGET-20-PANLIZ-09A-01D) from TARGET case TARGET-20-PANLIZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,102 days).
Specimen TARGET-20-PANLIZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03a99982-ebd8-446c-867b-daf0feb08ee8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANLIZ-14A (Bone Marrow Normal), aliquot TARGET-20-PANLIZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d192328-35d2-428d-abd0-adb3812b122b

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 2, Frame Shift Ins 2, Silent 2, In Frame Ins 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749299357, CM143849, COSV61632157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs118203537, CM991199, COSV53770216; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ELAVL1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV60966251; called by muse, mutect2, varscan2
- EZH2 | c.2211_2212insAATCCCCTC p.V737_G738insNPL (on ENST00000460911 / NM_001203247.2; = p.V742_G743insNPL on NM_004456.5) | In Frame Ins (INS) | VAF 10/86 reads (12%) | catalogued as COSV57461298, COSV57462628; called by mutect2, varscan2
- FCHSD1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs781678272, COSV51837536; called by muse, varscan2
- H2BC3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.108); catalogued as COSV63550866; called by muse, mutect2, varscan2
- KIRREL1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.462); catalogued as rs371294912, COSV63287960; called by muse, mutect2, varscan2
- ORM1 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs554585948, COSV52279401; called by muse, mutect2, varscan2
- POLQ | c.2774C>G p.S925C | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.416); catalogued as COSV99952347; called by muse, mutect2
- POMT2 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746000047, COSV55070060; called by muse, mutect2, varscan2
- PRKD1 | c.462C>A p.Y154* | Nonsense Mutation (SNP) | VAF 78/258 reads (30%) | catalogued as COSV59568778, COSV59570830; called by muse, mutect2, varscan2
- PTPRA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 121/344 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs773334274, COSV53780647; called by muse, mutect2, varscan2
- RAC2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as COSV50774468, COSV99969704; called by muse, mutect2, varscan2
- SRCAP | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52670805; called by muse, mutect2, varscan2
- TAS1R2 | c.2424C>A p.F808L | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64744954, COSV64747180; called by muse, mutect2, varscan2
- VIM | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs372258946; called by muse, mutect2
- ZNF527 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs375558431; called by muse, mutect2, varscan2
- ASXL2 | c.3781dup p.L1261Pfs*20 | Frame Shift Ins (INS) | VAF 28/149 reads (19%) | called by pindel, varscan2
- KRAS | c.36_38dup p.G13dup | In Frame Ins (INS) | VAF 56/220 reads (25%) | called by mutect2, pindel, varscan2
- PHIP | c.849dup p.R284Efs*23 | Frame Shift Ins (INS) | VAF 32/111 reads (29%) | called by mutect2, pindel, varscan2
- KCNIP3 | c.636G>A p.A212= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs763753766, COSV54665758; called by muse, mutect2, varscan2
- RPTOR | c.1230C>G p.A410= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as rs375864642, COSV60807121; called by muse, mutect2, varscan2
- CFAP74 | c.2176+34C>T | Intron (SNP) | VAF 21/58 reads (36%) | catalogued as rs562842260, COSV54566280, COSV54567624; called by muse, mutect2, varscan2
- MIR411 | n.34A>T | RNA (SNP) | VAF 10/269 reads (4%) | called by muse, mutect2
- NACA | c.71-4438_71-4437insGGGT | Intron (INS) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
